Somatic mutation profile of tumor specimen ALCH-AE0V-TTP1-A (aliquot ALCH-AE0V-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-AE0V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.8 years (20,007 days).
Specimen ALCH-AE0V-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a84f15d4-5b8d-468b-8720-0aeeb2c3d5c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0V-NB1-A (Blood Derived Normal), aliquot ALCH-AE0V-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8e4e7c1-af02-448b-9e73-eab643378303

The open-access MAF lists 237 somatic variants for this specimen: 161 protein-altering or splice-affecting, 42 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 42, Intron 12, Nonsense Mutation 11, Splice Site 8, 5'Flank 6, 3'UTR 6, RNA 5, 5'UTR 4, Frame Shift Del 4, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 109/558 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.840A>T p.R280S | Missense Mutation (SNP) | VAF 182/1052 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as CM136794, COSV52678283, COSV52782181, COSV52801834, COSV53205654; called by muse, mutect2, varscan2
- ADCY8 | c.3680G>T p.R1227L | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53902646; called by muse, mutect2, varscan2
- ADGB | c.4861G>T p.E1621* | Nonsense Mutation (SNP) | VAF 57/330 reads (17%) | catalogued as COSV100827430; called by muse, mutect2, varscan2
- AFTPH | c.2624G>T p.R875I (on ENST00000238855 / NM_203437.3; = p.R847I on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV53219577; called by muse, mutect2, varscan2
- AHCTF1 | c.1456C>T p.H486Y (on ENST00000366508; = p.H460Y on NM_015446.5) | Missense Mutation (SNP) | VAF 96/384 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1403380966; called by muse, mutect2, varscan2
- AHNAK2 | c.7327G>T p.E2443* | Nonsense Mutation (SNP) | VAF 88/384 reads (23%) | catalogued as rs200781097; called by muse, mutect2, varscan2
- ANXA10 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs771145957; called by muse, mutect2, varscan2
- ARSK | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV66170419; called by muse, mutect2, varscan2
- CACNA1D | c.5954C>A p.P1985Q (on ENST00000350061 / NM_001128840.3; = p.P2005Q on NM_000720.4) | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); catalogued as COSV99856264; called by muse, mutect2, varscan2
- CD300LD | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV60083296; called by muse, varscan2
- CDC123 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 116/692 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1564430178; called by muse, mutect2, varscan2
- CLRN1 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 166/1026 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.389); catalogued as COSV100184593; called by muse, mutect2
- COL3A1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 66/423 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as COSV100483675, COSV58591715; called by muse, mutect2, varscan2
- DBX2 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV60335936; called by muse, mutect2, varscan2
- DMBX1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV63602665; called by muse, mutect2, varscan2
- DNAJB5 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 136/693 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56626953; called by muse, mutect2, varscan2
- FGD5 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV99546953; called by muse, mutect2, varscan2
- FGF3 | c.672C>A p.H224Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs375708730, COSV61925621; called by muse, mutect2, varscan2
- FRK | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV73384053; called by muse, mutect2, varscan2
- GBA3 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776834779; called by muse, mutect2, varscan2
- IFI44L | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1367914874; called by muse, mutect2, varscan2
- IL1RAPL1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as COSV100144748; called by muse, mutect2, varscan2
- IMPG1 | c.175del p.R59Efs*28 | Frame Shift Del (DEL) | VAF 128/797 reads (16%) | catalogued as COSV64054288; called by mutect2, pindel, varscan2
- IRX3 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as COSV100315444, COSV61668197; called by muse, mutect2, varscan2
- KLHDC7A | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 63/279 reads (23%) | catalogued as COSV68769175; called by muse, mutect2, varscan2
- LAMC1 | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1176113807; called by muse, mutect2, varscan2
- LMBRD1 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 88/623 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65300091; called by muse, mutect2, varscan2
- MAGED1 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 214/412 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV58516195; called by muse, mutect2, varscan2
- MAP1A | c.252G>T p.W84C | Missense Mutation (SNP) | VAF 86/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55507249; called by muse, mutect2, varscan2
- MAX | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 249/1110 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99408607; called by muse, mutect2, varscan2
- MEN1 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1321063499; called by muse, mutect2, varscan2
- NACAD | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 25/189 reads (13%) | catalogued as COSV101512065; called by muse, mutect2, varscan2
- NKX3-2 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); catalogued as rs757624764, COSV66712189; called by muse, mutect2, varscan2
- NRXN1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV68051082; called by muse, mutect2, varscan2
- OR11H12 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 118/598 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs567303214; called by mutect2, varscan2
- OR13C8 | c.74C>G p.T25R | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58611107; called by muse, mutect2
- P3H2 | c.706G>C p.A236P | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1046171054; called by muse, mutect2
- PAPPA2 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 91/614 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV62776856, COSV62786106; called by muse, mutect2, varscan2
- PPP1R16B | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 84/437 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.751); catalogued as rs781126120; called by muse, mutect2, varscan2
- PTPN9 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs370582138; called by muse, mutect2, varscan2
- SPTA1 | c.6032C>A p.A2011D | Missense Mutation (SNP) | VAF 117/933 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV63749452, COSV63751452; called by muse, mutect2, varscan2
- TRIM49 | c.412-1G>T p.X138_splice | Splice Site (SNP) | VAF 20/300 reads (7%) | catalogued as COSV100315967; called by muse, mutect2, varscan2
- USP4 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 114/644 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748590334; called by muse, mutect2, varscan2
- WDR90 | c.5004+1G>T p.X1668_splice | Splice Site (SNP) | VAF 38/237 reads (16%) | catalogued as COSV99553297; called by muse, mutect2, varscan2
- ZAN | c.4692C>G p.C1564W | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61817169; called by muse, mutect2
- ZBTB5 | c.1220T>C p.F407S | Missense Mutation (SNP) | VAF 96/518 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs745742636; called by muse, mutect2
- ZNF566 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 109/492 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV101091678; called by muse, mutect2, varscan2
- ZNF648 | c.595T>A p.W199R | Missense Mutation (SNP) | VAF 74/673 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60570258; called by muse, mutect2, varscan2
- ABCA2 | c.7109G>A p.G2370D (on ENST00000614293; = p.G2340D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/462 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB11 | c.2483C>A p.T828K | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ABCB5 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ACKR1 | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 107/376 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ACTR2 | c.1104A>T p.K368N | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAM28 | c.2017T>A p.F673I | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ADAMTSL5 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AGTPBP1 | c.1761_1762del p.Q588Afs*10 (on ENST00000357081 / NM_001330701.2; = p.Q548Afs*10 on NM_015239.2) | Frame Shift Del (DEL) | VAF 59/357 reads (17%) | called by mutect2, pindel, varscan2
- ALG10 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 39/266 reads (15%) | called by muse, mutect2, varscan2
- ANGEL1 | c.1359C>A p.Y453* | Nonsense Mutation (SNP) | VAF 56/162 reads (35%) | called by muse, varscan2
- ANXA10 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF2 | c.2349G>T p.L783F | Missense Mutation (SNP) | VAF 134/816 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN2 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, varscan2
- BAMBI | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 75/529 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- BDP1 | c.556A>T p.M186L | Missense Mutation (SNP) | VAF 100/425 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- BMPER | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 60/428 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- BTK | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 351/694 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COQ2 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 120/754 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CRB1 | c.3859C>A p.P1287T | Missense Mutation (SNP) | VAF 79/690 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CRYBB1 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 106/648 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CSTF2 | c.1446G>T p.M482I | Missense Mutation (SNP) | VAF 240/413 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA3 | c.2629A>G p.K877E | Missense Mutation (SNP) | VAF 112/596 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- DGKH | c.3332A>T p.E1111V | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- DNAJB5 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 136/689 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DRD2 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DUOX1 | c.606C>G p.D202E | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FBRSL1 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FMO5 | c.1093_1098del p.T365_L366del | In Frame Del (DEL) | VAF 45/400 reads (11%) | called by mutect2, pindel, varscan2
- GAL3ST2 | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 83/520 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPR45 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- GRM3 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 87/510 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GYPC | c.83C>A p.T28K | Missense Mutation (SNP) | VAF 100/654 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HMCN1 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 126/1044 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HPSE2 | c.1564G>T p.V522F | Missense Mutation (SNP) | VAF 104/642 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTR1D | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLC3 | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 294/2562 reads (11%) | PolyPhen probably damaging (1); called by muse, varscan2
- IL17RA | c.1426G>T p.G476W | Missense Mutation (SNP) | VAF 114/620 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL17RA | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 114/626 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL1R2 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IL1RAPL1 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ITGA8 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 120/691 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- KAT6A | c.4926G>T p.R1642S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA0753 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA0895L | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KIAA1109 | c.4528T>A p.F1510I | Missense Mutation (SNP) | VAF 104/593 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LHX5 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LRP1B | c.11651-1G>T p.X3884_splice | Splice Site (SNP) | VAF 47/289 reads (16%) | called by muse, mutect2, varscan2
- LRP1B | c.5206G>T p.V1736F | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LRRC15 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 100/564 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LTF | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 82/480 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAP6D1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- MARCHF8 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MATK | c.927+2T>A p.X309_splice (on ENST00000310132 / NM_139355.3; = p.X310_splice on NM_002378.4) | Splice Site (SNP) | VAF 41/216 reads (19%) | called by muse, mutect2, varscan2
- MATN2 | c.1775G>A p.C592Y | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCCC1 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 62/452 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MUC2 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.22); called by muse, mutect2, varscan2
- MUC5AC | c.544A>T p.R182W | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NCBP3 | c.1681A>T p.K561* | Nonsense Mutation (SNP) | VAF 183/947 reads (19%) | called by muse, mutect2, varscan2
- NDUFA11 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- OR2A7 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 70/1076 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, varscan2
- OR2W3 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 117/932 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- OR8B8 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 74/343 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PCDHA3 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 146/992 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PDLIM3 | c.96C>A p.D32E (on ENST00000284770 / NM_001257963.1; = p.D111E on NM_014476.6) | Missense Mutation (SNP) | VAF 107/721 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- POMZP3 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PPL | c.3892T>A p.F1298I | Missense Mutation (SNP) | VAF 277/1006 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PPOX | c.223-4G>C | Splice Region (SNP) | VAF 217/1894 reads (11%) | called by muse, mutect2, varscan2
- PRLH | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- PRR14 | c.1268A>T p.E423V | Missense Mutation (SNP) | VAF 66/524 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PTCRA | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 133/768 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- RBMXL3 | c.718del p.R240Gfs*36 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- RPA1 | c.85-2A>G p.X29_splice | Splice Site (SNP) | VAF 37/204 reads (18%) | called by muse, mutect2, varscan2
- RYR2 | c.6088C>G p.L2030V | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2
- SAA1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 76/527 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SCN2A | c.267+1G>T p.X89_splice | Splice Site (SNP) | VAF 73/398 reads (18%) | called by muse, mutect2, varscan2
- SERAC1 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SLC1A3 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 334/773 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC7A4 | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMARCA4 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 181/1069 reads (17%) | called by muse, mutect2, varscan2
- SPTBN1 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- SRRM1 | c.1981A>G p.R661G | Missense Mutation (SNP) | VAF 167/918 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- STAB2 | c.332-2A>G p.X111_splice | Splice Site (SNP) | VAF 35/224 reads (16%) | called by muse, mutect2, varscan2
- SYCP2 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM2 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TEX15 | c.6842C>A p.P2281H (on ENST00000256246; = p.P2664H on NM_001350162.2) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TGFBR3 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 77/448 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- THRAP3 | c.1018G>T p.G340* | Nonsense Mutation (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- TIMD4 | c.77C>A p.T26N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.088); called by muse, varscan2
- TIMELESS | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TNFSF13 | c.400A>T p.T134S | Missense Mutation (SNP) | VAF 82/482 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TRIM15 | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TRIO | c.5262G>T p.Q1754H | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- TRIO | c.5445G>T p.Q1815H | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, varscan2
- TRPC3 | c.1339A>T p.R447W (on ENST00000379645 / NM_001366479.2; = p.R374W on NM_003305.2) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- TTC28 | c.3063G>T p.Q1021H | Missense Mutation (SNP) | VAF 121/906 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UNC5A | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UPF2 | c.3748C>G p.P1250A | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- URB1 | c.4955G>T p.R1652M | Missense Mutation (SNP) | VAF 169/696 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- WDR25 | c.1588G>T p.V530F | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- XPC | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 116/615 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLT1 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZBTB18 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 382/954 reads (40%) | called by muse, mutect2, varscan2
- ZBTB5 | c.1222A>G p.S408G | Missense Mutation (SNP) | VAF 96/518 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); called by muse, mutect2
- ZFHX4 | c.10046C>A p.T3349K | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZNF25 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF331 | c.627T>A p.H209Q | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF442 | c.968G>T p.C323F | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF460 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF551 | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZNF563 | c.1029del p.G345Afs*7 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | called by mutect2, pindel, varscan2
- ZNF879 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF880 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- AGAP3 | c.150C>T p.I50= (on ENST00000622464; = p.I86= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/501 reads (8%) | catalogued as COSV52543986; called by muse, mutect2
- AHDC1 | c.1125G>A p.G375= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs1348197909; called by muse, mutect2, varscan2
- ALOX15 | c.549C>A p.A183= | Silent (SNP) | VAF 79/318 reads (25%) | catalogued as rs147083325; called by muse, mutect2, varscan2
- APLNR | c.93C>A p.I31= | Silent (SNP) | VAF 49/247 reads (20%) | catalogued as rs576024496; called by muse, mutect2, varscan2
- ASAH2 | c.327T>A p.A109= | Silent (SNP) | VAF 92/514 reads (18%) | catalogued as rs767705180; called by muse, mutect2, varscan2
- CABS1 | c.543T>A p.R181= | Silent (SNP) | VAF 49/292 reads (17%) | called by muse, mutect2, varscan2
- CBLN2 | c.201G>T p.V67= | Silent (SNP) | VAF 59/357 reads (17%) | called by muse, mutect2, varscan2
- CSMD2 | c.1434G>T p.L478= | Silent (SNP) | VAF 96/450 reads (21%) | called by muse, mutect2, varscan2
- DMBX1 | c.186C>A p.A62= | Silent (SNP) | VAF 54/309 reads (17%) | called by muse, mutect2, varscan2
- DMRTC2 | c.621C>G p.P207= | Silent (SNP) | VAF 65/301 reads (22%) | catalogued as rs367552578, COSV54188374; called by muse, mutect2, varscan2
- DNAH9 | c.10311C>A p.A3437= | Silent (SNP) | VAF 82/497 reads (16%) | called by muse, mutect2, varscan2
- DPY19L1 | c.1581A>T p.V527= | Silent (SNP) | VAF 55/272 reads (20%) | called by muse, mutect2, varscan2
- ERICH3 | c.3000G>A p.E1000= | Silent (SNP) | VAF 72/381 reads (19%) | called by muse, mutect2, varscan2
- EYA2 | c.471G>T p.G157= | Silent (SNP) | VAF 80/506 reads (16%) | called by muse, mutect2, varscan2
- FKBP15 | c.1287A>T p.P429= | Silent (SNP) | VAF 48/278 reads (17%) | called by muse, mutect2, varscan2
- FLG | c.7509C>T p.A2503= | Silent (SNP) | VAF 122/1157 reads (11%) | catalogued as rs1246178357; called by muse, mutect2, varscan2
- FLT1 | c.2910C>A p.G970= | Silent (SNP) | VAF 192/676 reads (28%) | catalogued as rs762140333, COSV56729208; called by muse, varscan2
- IFNL1 | c.327C>A p.A109= | Silent (SNP) | VAF 54/321 reads (17%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2607G>T p.G869= (on ENST00000359125 / NM_172107.4; = p.G841= on NM_004518.6) | Silent (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- LDB3 | c.432T>G p.P144= | Silent (SNP) | VAF 57/433 reads (13%) | called by muse, mutect2, varscan2
- NAV3 | c.3675C>T p.A1225= | Silent (SNP) | VAF 57/331 reads (17%) | catalogued as rs1445408083; called by muse, mutect2, varscan2
- NKX2-6 | c.615G>T p.P205= | Silent (SNP) | VAF 122/618 reads (20%) | called by muse, varscan2
- NLRP3 | c.1293C>G p.A431= | Silent (SNP) | VAF 88/917 reads (10%) | catalogued as COSV60232012; called by muse, mutect2
- PCDHA3 | c.1740G>T p.L580= | Silent (SNP) | VAF 152/1003 reads (15%) | catalogued as rs782125982; called by muse, mutect2, varscan2
- PDE4DIP | c.3789G>A p.Q1263= | Silent (SNP) | VAF 70/422 reads (17%) | called by muse, mutect2, varscan2
- PGM5 | c.1011G>C p.G337= | Silent (SNP) | VAF 22/450 reads (5%) | catalogued as COSV67164227; called by muse, mutect2
- PI4KA | c.3807T>C p.A1269= | Silent (SNP) | VAF 108/624 reads (17%) | catalogued as rs1568968350; called by muse, mutect2, varscan2
- PRPH | c.213G>T p.L71= | Silent (SNP) | VAF 48/228 reads (21%) | catalogued as rs1223374982; called by muse, mutect2, varscan2
- RPL3L | c.30G>T p.R10= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV51907338; called by muse, mutect2, varscan2
- SI | c.1287A>G p.A429= | Silent (SNP) | VAF 101/609 reads (17%) | called by muse, mutect2, varscan2
- SLC5A12 | c.1533C>A p.G511= | Silent (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1734C>A p.I578= | Silent (SNP) | VAF 75/428 reads (18%) | called by muse, mutect2, varscan2
- SLFN11 | c.2589C>T p.S863= | Silent (SNP) | VAF 89/541 reads (16%) | called by muse, mutect2, varscan2
- SRPX2 | c.675C>T p.G225= | Silent (SNP) | VAF 126/251 reads (50%) | called by muse, mutect2, varscan2
- STAC | c.597C>A p.V199= | Silent (SNP) | VAF 70/353 reads (20%) | called by muse, mutect2, varscan2
- TAOK3 | c.12G>T p.G4= | Silent (SNP) | VAF 43/226 reads (19%) | called by muse, mutect2, varscan2
- TGFBR3 | c.2550G>T p.T850= | Silent (SNP) | VAF 83/461 reads (18%) | called by muse, mutect2, varscan2
- TRBV27 | c.15C>A p.L5= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- TRPC6 | c.2790T>C p.N930= | Silent (SNP) | VAF 63/325 reads (19%) | called by muse, mutect2, varscan2
- VAV3 | c.882C>T p.Y294= | Silent (SNP) | VAF 50/396 reads (13%) | called by muse, varscan2
- ZNF805 | c.88C>T p.L30= | Silent (SNP) | VAF 81/487 reads (17%) | called by muse, mutect2, varscan2
- ZNF862 | c.3255G>A p.Q1085= | Silent (SNP) | VAF 47/400 reads (12%) | catalogued as rs1239100963; called by muse, mutect2, varscan2
- ADAM21P1 | n.1693T>G | RNA (SNP) | VAF 63/329 reads (19%) | called by muse, mutect2, varscan2
- ADGRF4 | chr6:47693727 G>T | 5'Flank (SNP) | VAF 64/644 reads (10%) | called by muse, mutect2
- ADGRF4 | chr6:47693728 G>A | 5'Flank (SNP) | VAF 64/642 reads (10%) | catalogued as rs1206720051; called by muse, mutect2
- AL049777.1 | n.510+4526C>A | Intron (SNP) | VAF 93/285 reads (33%) | called by muse, mutect2, varscan2
- AP000356.3 | chr22:24644777 G>T | 5'Flank (SNP) | VAF 37/291 reads (13%) | catalogued as rs577209275; called by muse, mutect2, varscan2
- CHST6 | c.*33G>T | 3'UTR (SNP) | VAF 96/369 reads (26%) | catalogued as rs376468061, COSV100178356; called by muse, mutect2, varscan2
- DIABLO | c.-37+1276A>T | Intron (SNP) | VAF 128/839 reads (15%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.3019G>A | RNA (SNP) | VAF 31/311 reads (10%) | catalogued as rs1365572805; called by muse, mutect2, varscan2
- FOLH1B | n.1692T>A | RNA (SNP) | VAF 74/488 reads (15%) | called by muse, mutect2, varscan2
- FOXI2 | chr10:127736562 C>G | 5'Flank (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- GIPC1 | c.-30-6484C>G | Intron (SNP) | VAF 110/800 reads (14%) | called by muse, mutect2, varscan2
- GLYCTK | c.*990A>G | 3'UTR (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- GRIA2 | c.2406+465C>A | Intron (SNP) | VAF 44/342 reads (13%) | called by mutect2, varscan2
- GRM3 | c.-290C>T | 5'UTR (SNP) | VAF 110/592 reads (19%) | called by muse, mutect2, varscan2
- LY6H | c.68-68G>T | Intron (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- MFGE8 | c.*38G>T | 3'UTR (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30365057 G>T | 3'Flank (SNP) | VAF 51/236 reads (22%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12852G>T | Intron (SNP) | VAF 123/654 reads (19%) | called by muse, mutect2, varscan2
- NCOR2 | c.6411+38C>G | Intron (SNP) | VAF 82/377 reads (22%) | called by muse, mutect2, varscan2
- NEURL1 | c.86-15483C>G | Intron (SNP) | VAF 32/212 reads (15%) | called by muse, mutect2, varscan2
- OR2H2 | c.*2G>A | 3'UTR (SNP) | VAF 62/252 reads (25%) | catalogued as rs1276463360; called by muse, varscan2
- PIP5K1C | c.1920+1007C>A | Intron (SNP) | VAF 70/424 reads (17%) | called by muse, mutect2, varscan2
- PSG4 | c.-15C>T | 5'UTR (SNP) | VAF 43/224 reads (19%) | called by muse, mutect2, varscan2
- PTGFRN | c.-56G>A | 5'UTR (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77918978 C>T | 5'Flank (SNP) | VAF 131/1073 reads (12%) | called by muse, mutect2, varscan2
- SCN4B | c.62-18G>T | Intron (SNP) | VAF 136/932 reads (15%) | called by muse, mutect2, varscan2
- SETBP1 | c.540+7385G>C | Intron (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532547 G>T | 5'Flank (SNP) | VAF 131/1052 reads (12%) | catalogued as COSV99743941; called by muse, mutect2, varscan2
- TMEM161B | c.914+55G>T | Intron (SNP) | VAF 171/523 reads (33%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.-15C>A | 5'UTR (SNP) | VAF 113/409 reads (28%) | called by muse, mutect2, varscan2
- TUBB7P | n.1144G>T | RNA (SNP) | VAF 100/420 reads (24%) | catalogued as rs1349839367; called by muse, mutect2, varscan2
- UBR7 | c.*1982G>T | 3'UTR (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- ZNF849P | n.1073G>T | RNA (SNP) | VAF 52/381 reads (14%) | called by muse, varscan2
- ZNF99 | c.*2699C>A | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
